Gene-level copy-number profile of tumor specimen TCGA-XR-A8TG-01A from TCGA case TCGA-XR-A8TG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.0 years (21,544 days).
Specimen TCGA-XR-A8TG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.9f0f7913-c41b-4e71-91b1-89dcb76c029b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XR-A8TG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/796cc950-88c4-4bc8-839f-c12438f3af11

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 4,495; copy number 3: 988; copy number 4: 47,874; copy number 5: 131; copy number 6: 6,116; copy number 7: 83; copy number 8: 58; copy number 9: 41; copy number 10: 1; copy number 12: 9; copy number 13: 3; copy number 14: 17; copy number 15: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XR-A8TG-01A-11D-A35Y-01): tumor purity 0.79, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:90,631,906–90,632,568, 1 gene: TVP23CP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 56 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,070,578–151,538,692, 25 genes, copy number 9 (within-gene range 6–9): GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A, PSMD4, ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25, CGN, AL365436.3.
- chr1:228,776,312–228,858,556, 2 genes, copy number 12–15: AL078624.2, AL078624.1.
- chr2:203,634,577–203,672,423, 2 genes, copy number 9: AC125238.2, AC125238.1.
- chr9:134,293,931–134,295,397, 1 gene, copy number 10: LINC02247.
- chr19:11,089,462–11,197,791, 4 genes, copy number 12: LDLR, MIR6886, SPC24, KANK2.
- chr20:34,194,569–34,540,958, 17 genes, copy number 14: ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA.
- chr20:50,292,709–50,585,241, 5 genes, copy number 9–13 (within-gene range 4–13): LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
